Gene-level copy-number profile of tumor specimen TCGA-AQ-A54O-01A from TCGA case TCGA-AQ-A54O, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.2 years (18,694 days).
Specimen TCGA-AQ-A54O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.f9396883-7828-4aaf-b487-9deec4e199fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AQ-A54O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3123dc34-624a-4bb4-a3a2-815bcb3f8058

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,829; copy number 2: 27,796; copy number 3: 21,733; copy number 4: 4,890; copy number 5: 90; copy number 6: 75; copy number 7: 240; copy number 8: 167.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AQ-A54O-01A-11D-A25N-01): tumor purity 0.74, ploidy 2.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 572 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:39,213,777–41,618,384, 31 genes, copy number 5: LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11.
- chr20:43,914,852–64,313,132, 541 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,829. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
